FM case AD7002 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/31650961-ddb8-4458-9ff7-499e2d3a71b1

Male, 48.2 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the liver. Sample type: Tumor.
